Surgical pathology report (de-identified scan), TCGA case TCGA-VS-A94Z, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma), tissue source site Barretos Cancer Hospital, specimen TCGA-VS-A94Z-01A (Primary Tumor).

ICD-O-3
Carcinoma, squamous cell NOS
807013
Site Cervix NOS
C53.9
W 3/12/14

PATHOLOGY REPORT:

PRIMARY SITE: Cervix

1-"Biopsy of uterine cervix":

- Squamous cell carcinoma, moderately differentiated in this sample, invasive.

ICDPA Discrepancy		☒
Case is "outlet"		☒
Revised Initials	MA	Date Re-evaluated: 4/12/13

Source: NCI Genomic Data Commons file 0a55be95-1bfb-4fc4-87c2-5b5dd881ee3b (TCGA-VS-A94Z.8B8D851A-EF25-4052-9BD7-95248B923C6C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).